Gene-level copy-number profile of tumor specimen TCGA-QR-A703-01A from TCGA case TCGA-QR-A703, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 23.1 years (8,421 days).
Specimen TCGA-QR-A703-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PCPG.cb92df14-8fe8-43d6-8cc2-5fe6520d3949.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-QR-A703-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate.
https://portal.gdc.cancer.gov/files/3c63019c-2f47-47f4-b7d2-aabccb1fd37a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 43; copy number 1: 9,866; copy number 2: 49,487; copy number 3: 422.

Homozygous deletions (total copy number 0; autosomes only): 42 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:35,650,197–35,651,961, 1 gene: ARPP21-AS1.
- chr3:77,567,508–77,571,881, 1 gene: AC133040.1.
- chr3:105,366,909–105,576,900, 1 gene (within-gene range 0–1): ALCAM.
- chr5:67,800,740–67,890,096, 2 genes (within-gene range 0–2): AC024581.1, AC024581.2.
- chr5:155,491,336–155,493,598, 1 gene: AC008725.1.
- chr6:22,589,137–22,593,833, 1 gene: AL033539.1.
- chr6:77,496,119–77,496,671, 1 gene: RPS6P7.
- chr6:85,257,328–85,257,694, 1 gene: AL122016.1.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr7:126,495,312–126,531,336, 2 genes (within-gene range 0–2): AC002057.2, AC000374.1.
- chr7:136,903,167–136,903,294, 1 gene: MIR490.
- chr8:43,672,823–43,674,591, 2 genes: AC139365.2, AC139365.1.
- chr8:46,810,696–46,907,309, 9 genes (within-gene range 0–2): AC021451.2, AC021451.3, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3.
- chr8:131,712,512–131,712,980, 1 gene: AC060788.1.
- chr9:80,563,571–80,565,962, 2 genes: MTCO1P51, MTND2P9.
- chr11:21,260,061–21,262,570, 1 gene: AC090857.2.
- chr11:25,924,188–25,926,808, 1 gene: AC013799.1.
- chr11:50,409,042–50,422,316, 1 gene: AC024405.1.
- chr12:28,505,394–28,505,528, 1 gene: RNA5SP355.
- chr12:42,929,848–42,930,579, 1 gene: AC068802.1.
- chr12:46,764,761–46,832,408, 1 gene (within-gene range 0–2): SLC38A4.
- chr14:21,887,857–21,924,651, 5 genes: TRAV12-2, TRAV8-4, TRAV8-5, TRAV13-2, TRAV14DV4.
- chr19:27,638,483–27,794,005, 4 genes (within-gene range 0–2): ERVK-28, AC112702.1, LINC00662, AC006504.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,486. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
